Somatic mutation profile of tumor specimen 0DDX8R from CCDI case PBBMZW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 22.3 years (8,140 days).
Specimen 0DDX8R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f91d0440-04c5-46b2-b9b4-6f8173fb78c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDX65 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7a4f85c-a54c-4eae-8172-ecff19866ca2

The open-access MAF lists 3,150 somatic variants for this specimen: 1,980 protein-altering or splice-affecting, 454 silent, 716 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,679, Intron 474, Silent 454, Nonsense Mutation 229, 3'UTR 146, 5'UTR 64, Splice Site 35, Splice Region 31, 3'Flank 12, RNA 12, 5'Flank 8, Nonstop Mutation 4.

Variants (750 of 3,150; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.9538C>T p.R3180* | Nonsense Mutation (SNP) | VAF 410/1016 reads (40%) | catalogued as rs563393715, CM150672, HM0690; ClinVar: pathogenic; called by muse, varscan2
- ASL | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 166/430 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199938613, CM141220, COSV100508883; ClinVar: likely pathogenic; called by muse, varscan2
- ATRX | c.5026G>T p.G1676C | Missense Mutation (SNP) | VAF 574/1433 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1557106484; ClinVar: likely pathogenic; called by muse, varscan2
- COL4A3 | c.4486C>T p.R1496* | Nonsense Mutation (SNP) | VAF 300/678 reads (44%) | catalogued as rs769863513, CM052202, COSV67420825; ClinVar: likely pathogenic; called by muse, varscan2
- LHCGR | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 542/1434 reads (38%) | catalogued as rs121912524, CM960940, COSV54292419; ClinVar: pathogenic; called by muse, varscan2
- PIK3CA | c.1049A>G p.D350G | Missense Mutation (SNP) | VAF 260/594 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs1553821144, COSV55877939, COSV55937337; ClinVar: uncertain significance; called by muse, varscan2
- SLC26A3 | c.1696C>T p.R566* | Nonsense Mutation (SNP) | VAF 582/1380 reads (42%) | catalogued as rs1018933248, COSV60641463; ClinVar: pathogenic; called by muse, varscan2
- TMCO1 | c.544C>T p.R182* (on ENST00000612311 / NM_001256164.1; = p.R131* on NM_019026.6) | Nonsense Mutation (SNP) | VAF 474/1147 reads (41%) | catalogued as rs1247427997; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 489/552 reads (89%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- AADAT | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 188/750 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV100528764; called by muse, varscan2
- AARS1 | c.1185G>T p.R395S | Missense Mutation (SNP) | VAF 318/756 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.904); catalogued as COSV55747004; called by muse, varscan2
- ABCA12 | c.4544G>A p.R1515Q (on ENST00000272895 / NM_173076.3; = p.R1197Q on NM_015657.3) | Missense Mutation (SNP) | VAF 282/798 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs774279263, CM1311790, COSV55948366; called by muse, varscan2
- ABCA13 | c.410G>T p.R137I | Missense Mutation (SNP) | VAF 472/1112 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as rs201247339, COSV101330000; called by muse, varscan2
- ABCA4 | c.4070C>T p.A1357V | Missense Mutation (SNP) | VAF 282/721 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as CM1311043, CM159965; called by muse, varscan2
- ABCA4 | c.750C>A p.F250L | Missense Mutation (SNP) | VAF 166/926 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1459168634; called by muse, varscan2
- ABCB4 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 196/1020 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55938503; called by muse, varscan2
- ACAP1 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 291/720 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs759890204; called by muse, varscan2
- ACE2 | c.1805C>A p.S602Y | Missense Mutation (SNP) | VAF 496/1222 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV53024390; called by muse, varscan2
- ACSM2A | c.1343G>A p.G448E (on ENST00000219054; = p.G369E on NM_001308169.2) | Missense Mutation (SNP) | VAF 82/700 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs751254094, COSV54584996; called by muse, varscan2
- ACSM2B | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 154/1213 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs774547919, COSV61657965; called by muse, varscan2
- ACTG2 | c.182G>A p.S61N | Missense Mutation (SNP) | VAF 160/890 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); catalogued as COSV61828147; called by muse, varscan2
- ACTR3B | c.687G>T p.E229D | Missense Mutation (SNP) | VAF 315/1099 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV99754647; called by muse, varscan2
- ADAM9 | c.2174G>A p.R725K | Missense Mutation (SNP) | VAF 472/1235 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV65961267, COSV65961498; called by muse, varscan2
- ADAMTS12 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 472/1164 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as rs144557630, COSV100711718; called by muse, varscan2
- ADAMTS5 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 370/866 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755042708, COSV53177133; called by muse, varscan2
- ADAMTS6 | c.2166C>A p.F722L | Missense Mutation (SNP) | VAF 338/852 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV66863751; called by muse, varscan2
- ADAMTSL3 | c.2372C>T p.T791M | Missense Mutation (SNP) | VAF 66/610 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.509); catalogued as rs144077662, COSV54450723; called by muse, varscan2
- ADCY7 | c.3014G>A p.R1005Q | Missense Mutation (SNP) | VAF 318/746 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0.11); catalogued as rs554409790; called by muse, varscan2
- ADGRF4 | c.1098G>T p.M366I | Missense Mutation (SNP) | VAF 462/1119 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as COSV51957462; called by muse, varscan2
- AFDN | c.4936G>A p.A1646T (on ENST00000447894 / NM_001366320.1; = p.A1644T on NM_001040000.3) | Missense Mutation (SNP) | VAF 210/1022 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.953); catalogued as rs150601242, COSV60038422; called by muse, varscan2
- AFM | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 465/1129 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.817); catalogued as rs373279626; called by muse, varscan2
- AGBL4 | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 436/1036 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV65738543; called by muse, varscan2
- AGFG2 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 396/870 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV53547010; called by muse, varscan2
- AHCTF1 | c.5789C>T p.T1930M (on ENST00000366508; = p.T1904M on NM_015446.5) | Missense Mutation (SNP) | VAF 142/1290 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs763625624; called by muse, varscan2
- AHNAK | c.3724G>T p.D1242Y | Missense Mutation (SNP) | VAF 356/936 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99947330; called by muse, varscan2
- AHNAK2 | c.9444C>A p.F3148L | Missense Mutation (SNP) | VAF 169/236 reads (72%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV60923941; called by muse, varscan2
- AIM2 | c.612G>T p.K204N | Missense Mutation (SNP) | VAF 524/1302 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV63698440, COSV63702008; called by muse, varscan2
- AKAP7 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 540/1282 reads (42%) | catalogued as rs754751702, COSV53834357; called by muse, varscan2
- AKAP9 | c.8119G>T p.E2707* (on ENST00000359028; = p.E2683* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 516/1200 reads (43%) | catalogued as COSV62337878; called by muse, varscan2
- AKR1E2 | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 262/620 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs140861331; called by muse, varscan2
- ALAS1 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 124/1166 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as rs761283191, COSV59627723; called by muse, varscan2
- ALMS1 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 320/782 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs769734500, COSV52507633; called by muse, varscan2
- ALOX12B | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 344/764 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768784091, CM162710; called by muse, varscan2
- AMER1 | c.268C>A p.L90I | Missense Mutation (SNP) | VAF 203/589 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as rs781369600, COSV57668751; called by muse, varscan2
- ANKAR | c.2608C>A p.L870I | Missense Mutation (SNP) | VAF 354/805 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs200831821, COSV55609455; called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.4231G>A p.E1411K | Missense Mutation (SNP) | VAF 308/728 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as rs949524880, COSV51841395; called by muse, varscan2
- ANKK1 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 310/688 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.204); catalogued as rs200103052, COSV58275116; called by muse, varscan2
- ANKMY1 | c.51C>A p.F17L | Missense Mutation (SNP) | VAF 297/633 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs375514209; called by muse, varscan2
- ANKRD17 | c.1540G>T p.E514* | Nonsense Mutation (SNP) | VAF 162/1147 reads (14%) | catalogued as COSV58224019; called by muse, varscan2
- ANKRD22 | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 464/1348 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1430391353; called by muse, varscan2
- ANKRD26 | c.4159G>A p.D1387N | Missense Mutation (SNP) | VAF 224/636 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.924); catalogued as rs1221890358; called by muse, varscan2
- ANKRD30A | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 128/271 reads (47%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.559); catalogued as COSV100652676; called by muse, varscan2
- ANKRD30A | c.2839G>T p.E947* (on ENST00000611781; = p.E891* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 390/976 reads (40%) | catalogued as rs371663598, COSV64603807; called by muse, varscan2
- ANKRD30B | c.3598G>T p.E1200* | Nonsense Mutation (SNP) | VAF 496/1386 reads (36%) | catalogued as COSV100271184, COSV57702984; called by muse, varscan2
- ANKRD33 | c.638G>A p.R213Q (on ENST00000340970 / NM_001304459.2; = p.R338Q on NM_182608.4) | Missense Mutation (SNP) | VAF 256/677 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs369237129; called by muse, varscan2
- ANKRD50 | c.170C>A p.S57Y | Missense Mutation (SNP) | VAF 644/1196 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); catalogued as COSV72385950; called by muse, varscan2
- ANO2 | c.994G>T p.E332* (on ENST00000356134 / NM_001278597.3; = p.E336* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 247/538 reads (46%) | catalogued as COSV59028721; called by muse, varscan2
- ANO3 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 552/682 reads (81%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs760680753, COSV56807795, COSV99882662; called by muse, varscan2
- ANO6 | c.1744G>T p.D582Y | Missense Mutation (SNP) | VAF 547/1274 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs755579389, COSV100262495; called by muse, varscan2
- AP3B1 | c.1091G>T p.R364I | Missense Mutation (SNP) | VAF 363/953 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV54880967; called by muse, varscan2
- APOB | c.12698C>T p.S4233L | Missense Mutation (SNP) | VAF 402/914 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs377125320, COSV51925242; called by muse, varscan2
- AREL1 | c.1370G>T p.R457I | Missense Mutation (SNP) | VAF 321/840 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV100707667; called by muse, varscan2
- ARFGEF2 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 501/1162 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs748227723, COSV64212843; called by muse, varscan2
- ARHGAP12 | c.1452G>T p.K484N | Missense Mutation (SNP) | VAF 475/1155 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV60962390; called by muse, varscan2
- ARHGAP24 | c.1495C>T p.R499* (on ENST00000395184 / NM_001025616.3; = p.R406* on NM_031305.3) | Nonsense Mutation (SNP) | VAF 591/1422 reads (42%) | catalogued as COSV51987040; called by muse, varscan2
- ARHGEF37 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 410/988 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs567909765, COSV61367758; called by muse, varscan2
- ARID2 | c.5008G>A p.E1670K | Missense Mutation (SNP) | VAF 543/1145 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); catalogued as COSV57613450; called by muse, varscan2
- ARID4A | c.3698C>A p.S1233Y | Missense Mutation (SNP) | VAF 343/984 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100794176; called by muse, varscan2
- ARNT | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 317/811 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62230780; called by muse, varscan2
- ARPP21 | c.2033-5C>T | Splice Region (SNP) | VAF 391/1042 reads (38%) | catalogued as rs771346632; called by muse, varscan2
- ASB15 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 484/1259 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV51924871; called by muse, varscan2
- ASCC3 | c.890C>A p.S297Y | Missense Mutation (SNP) | VAF 651/1693 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1319705944, COSV100226515; called by muse, varscan2
- ASH1L | c.8065C>T p.R2689* (on ENST00000368346 / NM_001366177.2; = p.R2684* on NM_018489.3) | Nonsense Mutation (SNP) | VAF 415/1012 reads (41%) | catalogued as COSV100853198; called by muse, varscan2
- ASPRV1 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 290/756 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1435874677; called by muse, varscan2
- ATIC | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 224/676 reads (33%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.623); catalogued as rs756173162, COSV52695840; called by muse, varscan2
- ATM | c.7382G>A p.R2461H | Missense Mutation (SNP) | VAF 438/1176 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs768461085, COSV53782078, COSV99590879; ClinVar: uncertain significance; called by muse, varscan2
- ATP10A | c.3969G>T p.E1323D | Missense Mutation (SNP) | VAF 312/814 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs745618857; called by muse, varscan2
- ATP13A5 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 148/1418 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.192); catalogued as COSV60868511; called by muse, varscan2
- ATP1A2 | c.2739C>A p.F913L | Missense Mutation (SNP) | VAF 220/526 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV63403788; called by muse, varscan2
- ATP2B1 | c.3374G>A p.R1125H | Missense Mutation (SNP) | VAF 86/744 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.695); catalogued as rs1477181244; called by muse, varscan2
- ATXN2L | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 152/654 reads (23%) | catalogued as COSV100294330, COSV57376322; called by muse, varscan2
- AURKAIP1 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 248/571 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs761951438; called by muse, varscan2
- B3GALNT1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 398/1196 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs752083614, COSV57581127; called by muse, varscan2
- B3GNT4 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 214/570 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs942692043, COSV57336917; called by muse, varscan2
- B4GALNT3 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 212/518 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756076751, COSV56750072, COSV99842427; called by muse, varscan2
- BACE2 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 826/956 reads (86%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs1176548713; called by muse, varscan2
- BAHD1 | c.2118G>T p.E706D | Missense Mutation (SNP) | VAF 243/341 reads (71%) | SIFT tolerated (0.63); PolyPhen benign (0.164); catalogued as rs1038984924; called by muse, varscan2
- BARD1 | c.1137A>C p.K379N | Missense Mutation (SNP) | VAF 130/1198 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1060501306; ClinVar: uncertain significance; called by muse, varscan2
- BBX | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 424/1235 reads (34%) | catalogued as COSV100361987, COSV57880187, COSV57881301; called by muse, varscan2
- BCAT1 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 416/1056 reads (39%) | catalogued as rs760034705; called by muse, varscan2
- BCKDK | c.717-4G>A | Splice Region (SNP) | VAF 276/546 reads (51%) | catalogued as rs200045337, COSV54890388; called by muse, varscan2
- BCL11B | c.1363T>C p.Y455H (on ENST00000357195 / NM_001282237.2; = p.Y384H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/256 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61733042, COSV61736973; called by muse, varscan2
- BCL9 | c.2035C>T p.R679* | Nonsense Mutation (SNP) | VAF 253/661 reads (38%) | catalogued as COSV52350345; called by muse, varscan2
- BDP1 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 354/866 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs759542204; called by muse, varscan2
- BEND3 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 126/641 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.749); catalogued as rs782720317; called by muse, varscan2
- BICD2 | c.2348G>A p.R783H | Missense Mutation (SNP) | VAF 287/624 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756670700, COSV63547915; called by muse, varscan2
- BLM | c.3278C>A p.S1093* | Nonsense Mutation (SNP) | VAF 166/541 reads (31%) | catalogued as CM072898; called by muse, varscan2
- BMP2K | c.3442G>A p.E1148K | Missense Mutation (SNP) | VAF 528/1318 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as rs754970059, COSV55008366; called by muse, varscan2
- BMP5 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 143/1315 reads (11%) | catalogued as COSV63706517; called by muse, varscan2
- BMP7 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 88/863 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as rs772689429; called by muse, varscan2
- BMPR2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 336/717 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.248); catalogued as rs1085307204, CM094639, CM100457, COSV101001509; ClinVar: uncertain significance; called by muse, varscan2
- BROX | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 587/1522 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs1356567913, COSV61799034; called by muse, varscan2
- BRPF3 | c.3217G>T p.D1073Y | Missense Mutation (SNP) | VAF 250/638 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV60209802; called by muse, varscan2
- BRWD1 | c.4796G>A p.R1599Q | Missense Mutation (SNP) | VAF 522/1252 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs1342412921; called by muse, varscan2
- BRWD1 | c.3632G>A p.R1211Q | Missense Mutation (SNP) | VAF 506/1219 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1201433907, COSV60893554; called by muse, varscan2
- BRWD1 | c.1955C>T p.S652L | Missense Mutation (SNP) | VAF 475/1081 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs751937145; called by muse, varscan2
- BTBD3 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 602/1257 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs200448067, COSV54780771; called by muse, varscan2
- BTRC | c.1256G>T p.R419L (on ENST00000370187 / NM_033637.4; = p.R383L on NM_003939.5) | Missense Mutation (SNP) | VAF 339/812 reads (42%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.541); catalogued as COSV64579389; called by muse, varscan2
- C11orf54 | c.694G>T p.E232* (on ENST00000331239; = p.E182* on NM_014039.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 479/1170 reads (41%) | catalogued as rs747509218; called by muse, varscan2
- C12orf50 | c.869G>T p.R290I | Missense Mutation (SNP) | VAF 428/1054 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV53898675; called by muse, varscan2
- C18orf54 | c.101C>A p.S34Y | Missense Mutation (SNP) | VAF 590/1456 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100266568; called by muse, varscan2
- C1orf43 | c.595C>T p.R199* (on ENST00000368521 / NM_001297718.2; = p.R165* on NM_015449.4) | Nonsense Mutation (SNP) | VAF 288/772 reads (37%) | catalogued as rs890788530, COSV62966903; called by muse, varscan2
- C1orf87 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 248/1296 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as rs772529746, COSV64598000, COSV64599212; called by muse, varscan2
- C1orf94 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 370/932 reads (40%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1214589775, COSV64915708; called by muse, varscan2
- C2CD5 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 465/1168 reads (40%) | catalogued as COSV61723130, COSV61724471; called by muse, varscan2
- C2CD5 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 512/1454 reads (35%) | catalogued as rs962490949, COSV61724056; called by muse, varscan2
- CA10 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 449/1091 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780641204, COSV53353383; called by muse, varscan2
- CA12 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 60/473 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51604353; called by muse, varscan2
- CAAP1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 594/1474 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as rs370258315, COSV61701450; called by muse, varscan2
- CACNA1A | c.2127C>A p.F709L | Missense Mutation (SNP) | VAF 167/522 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs762654239; ClinVar: uncertain significance; called by muse, varscan2
- CACNA1D | c.4664G>A p.R1555Q (on ENST00000350061 / NM_001128840.3; = p.R1575Q on NM_000720.4) | Missense Mutation (SNP) | VAF 690/1560 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs765670623, COSV55445331; called by muse, varscan2
- CALB2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 287/718 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as rs867906130, COSV100226115; called by muse, varscan2
- CAMK2G | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 270/686 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99990401; called by muse, varscan2
- CAPN12 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 192/470 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.727); catalogued as rs776674497, COSV61018898; called by muse, varscan2
- CAPN7 | c.2016T>G p.Y672* | Nonsense Mutation (SNP) | VAF 348/881 reads (40%) | catalogued as COSV99512676; called by muse, varscan2
- CAPRIN2 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 666/1535 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs138797190; called by muse, varscan2
- CASP8AP2 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 353/842 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.051); catalogued as rs758643574, COSV52746227; called by muse, varscan2
- CC2D1A | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 60/298 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1166152440; called by muse, varscan2
- CCDC168 | c.21097C>T p.R7033C | Missense Mutation (SNP) | VAF 610/772 reads (79%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1364171178; called by muse, varscan2
- CCDC170 | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 260/1480 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.156); catalogued as COSV53339425, COSV53342182; called by muse, varscan2
- CCDC60 | c.306G>T p.K102N | Missense Mutation (SNP) | VAF 108/939 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.801); catalogued as rs267603333; called by muse, varscan2
- CCDC7 | c.2245G>T p.E749* | Nonsense Mutation (SNP) | VAF 386/1002 reads (39%) | catalogued as COSV56552738; called by muse, varscan2
- CCDC71 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 244/588 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs575570560, COSV58910544; called by muse, varscan2
- CCDC80 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 281/572 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV52816574; called by muse, varscan2
- CCDC81 | c.1004G>A p.R335Q (on ENST00000445632 / NM_001156474.2; = p.R245Q on NM_021827.4) | Missense Mutation (SNP) | VAF 415/1093 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs868030464, COSV53577858; called by muse, varscan2
- CCDC88A | c.2254G>T p.E752* | Nonsense Mutation (SNP) | VAF 625/1554 reads (40%) | catalogued as COSV55058868; called by muse, varscan2
- CCDC91 | c.461G>T p.R154I | Missense Mutation (SNP) | VAF 161/843 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs774693971, COSV60347182; called by muse, varscan2
- CD101 | c.2616G>T p.E872D | Missense Mutation (SNP) | VAF 424/972 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV56719792; called by muse, varscan2
- CD164L2 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 74/395 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs1284242991, COSV64995701; called by muse, varscan2
- CD247 | c.460G>A p.D154N (on ENST00000362089 / NM_198053.3; = p.D153N on NM_000734.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 312/753 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs984740029, COSV54814753, COSV54818986; called by muse, varscan2
- CD247 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 259/685 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV62978366, COSV62979101; called by muse, varscan2
- CD2AP | c.1009-1G>T p.X337_splice | Splice Site (SNP) | VAF 218/1200 reads (18%) | catalogued as COSV63760515; called by muse, varscan2
- CD83 | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 246/640 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as COSV64788560; called by muse, varscan2
- CDC5L | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 528/1250 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101014906, COSV65175715; called by muse, varscan2
- CDH23 | c.4783G>A p.E1595K | Missense Mutation (SNP) | VAF 166/862 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as rs778204574, CM021543, COSV99824026; called by muse, varscan2
- CDH7 | c.1603G>T p.D535Y | Missense Mutation (SNP) | VAF 412/1046 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59882256, COSV59885618; called by muse, varscan2
- CDIPT | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 132/554 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1054446868, COSV99570139; called by muse, varscan2
- CDK12 | c.2644C>T p.R882W | Missense Mutation (SNP) | VAF 354/926 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70999496; called by muse, varscan2
- CDK13 | c.2716G>A p.E906K | Missense Mutation (SNP) | VAF 456/1138 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1554335512, COSV51703082, COSV99476032; ClinVar: uncertain significance; called by muse, varscan2
- CDK13 | c.3458C>T p.S1153L | Missense Mutation (SNP) | VAF 592/1338 reads (44%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs933601432, COSV51697832; called by muse, varscan2
- CEACAM4 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 214/548 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.018); catalogued as rs1555803685, COSV99700952; called by muse, varscan2
- CENPJ | c.2792G>A p.R931H | Missense Mutation (SNP) | VAF 476/1248 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs751033744; called by muse, varscan2
- CEP120 | c.1627G>T p.D543Y | Missense Mutation (SNP) | VAF 205/1370 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60268487; called by muse, varscan2
- CEP170B | c.4350G>T p.E1450D (on ENST00000453495; = p.E1379D on NM_015005.3) | Missense Mutation (SNP) | VAF 58/525 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV52044324; called by muse, varscan2
- CEP192 | c.6211G>T p.E2071* | Nonsense Mutation (SNP) | VAF 342/852 reads (40%) | catalogued as rs781720989, COSV100381934; called by muse, varscan2
- CEP192 | c.6935C>T p.A2312V | Missense Mutation (SNP) | VAF 268/750 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs758669979, COSV100381481; called by muse, varscan2
- CFAP36 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 282/729 reads (39%) | catalogued as COSV59119168; called by muse, varscan2
- CFAP92 | c.3088G>A p.D1030N | Missense Mutation (SNP) | VAF 430/918 reads (47%) | SIFT tolerated (0.98); PolyPhen benign (0.063); catalogued as rs771877831; called by muse, varscan2
- CFAP94 | c.539T>G p.F180C (on ENST00000320267 / NM_001352064.2; = p.F186C on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 403/1034 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs1315107413; called by muse, varscan2
- CFAP97 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 198/869 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs373566490, COSV57109285; called by muse, varscan2
- CFTR | c.3089G>T p.R1030I | Missense Mutation (SNP) | VAF 574/1468 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99140154; called by muse, varscan2
- CHD3 | c.2798G>T p.R933I | Missense Mutation (SNP) | VAF 281/672 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100391493; called by muse, varscan2
- CHRM5 | c.986G>A p.G329D | Missense Mutation (SNP) | VAF 351/425 reads (83%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs780268468, COSV67247054; called by muse, varscan2
- CHRNA10 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 288/365 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765656579, COSV51705145; called by muse, varscan2
- CHRNB1 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 194/450 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142822694; called by muse, varscan2
- CHST13 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 45/437 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV60043373; called by muse, varscan2
- CHTF18 | c.2181G>T p.Q727H | Missense Mutation (SNP) | VAF 51/346 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as COSV50211004; called by muse, varscan2
- CIPC | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 226/555 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as rs773785918, COSV62376759; called by muse, varscan2
- CLASP1 | c.3583C>T p.R1195* | Nonsense Mutation (SNP) | VAF 598/1394 reads (43%) | catalogued as COSV99754098; called by muse, varscan2
- CLCN1 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 550/1400 reads (39%) | catalogued as rs956078618, CM960302; called by muse, varscan2
- CLDN10 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 302/798 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV54824219; called by muse, varscan2
- CLIP2 | c.1648C>T p.L550F | Missense Mutation (SNP) | VAF 186/402 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as rs1554312747; called by muse, varscan2
- CLPB | c.735C>T p.G245= | Splice Region (SNP) | VAF 88/606 reads (15%) | catalogued as rs201151763, COSV53635295; called by muse, varscan2
- CLTRN | c.71C>A p.A24D | Missense Mutation (SNP) | VAF 187/1289 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs868698471; called by muse, varscan2
- CNKSR2 | c.470G>T p.R157I | Missense Mutation (SNP) | VAF 388/950 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99669128; called by muse, varscan2
- CNKSR3 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 477/1180 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1223415726; called by muse, varscan2
- CNOT6 | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 487/1176 reads (41%) | catalogued as COSV99993660; called by muse, varscan2
- CNOT7 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 648/1646 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1402157230, COSV104420109, COSV63517661; called by muse, varscan2
- CNTLN | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 256/702 reads (36%) | catalogued as COSV52077560; called by muse, varscan2
- CNTNAP1 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 128/716 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs755070825, COSV99226140, COSV99226997; called by muse, varscan2
- COL1A1 | c.4008C>A p.F1336L | Missense Mutation (SNP) | VAF 40/365 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV56802169; called by muse, varscan2
- COL5A2 | c.3412G>A p.D1138N | Missense Mutation (SNP) | VAF 348/1048 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.5); catalogued as rs750574093; called by muse, varscan2
- COL6A5 | c.5302G>A p.D1768N (on ENST00000312481; = p.D1764N on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 321/941 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.616); catalogued as rs186272804, COSV55215331; called by muse, varscan2
- COL6A6 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 734/1588 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); catalogued as rs1384228206, COSV62020153; called by muse, varscan2
- COL9A1 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 298/742 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs1158012793, COSV57888008; called by muse, varscan2
- COL9A2 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 143/317 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs749078666, COSV101028743; called by muse, varscan2
- COPS2 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 440/588 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs769174765; called by muse, varscan2
- COX10 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 324/705 reads (46%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs868542723; called by muse, varscan2
- CPM | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 228/670 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs200496918, COSV100615112; called by muse, varscan2
- CPT1A | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 388/824 reads (47%) | catalogued as rs767241290; called by muse, varscan2
- CPXCR1 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 100/569 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774253645, COSV52161728; called by muse, varscan2
- CPXM1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 65/662 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs759693140; called by muse, varscan2
- CRB2 | c.3113G>A p.R1038Q | Missense Mutation (SNP) | VAF 202/429 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.212); catalogued as rs764259390; called by muse, varscan2
- CREB1 | c.284G>T p.R95I | Missense Mutation (SNP) | VAF 650/1462 reads (44%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.308); catalogued as COSV62065530; called by muse, varscan2
- CREB3 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 458/1132 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as rs779704350; called by muse, varscan2
- CRISP2 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 438/1214 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1317921998; called by muse, varscan2
- CRP | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 38/354 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.723); catalogued as COSV54813729; called by muse, varscan2
- CRYBG1 | c.3704C>T p.S1235L | Missense Mutation (SNP) | VAF 468/1122 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226140016; called by muse, varscan2
- CSF2RA | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 242/553 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs777638014, COSV62623722; called by muse, varscan2
- CSF3R | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 185/461 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.182); catalogued as COSV58968735; called by muse, varscan2
- CTAGE9 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 70/606 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1395805446; called by muse, varscan2
- CTTNBP2 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 280/1455 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778052265, COSV50392847; called by muse, varscan2
- CUBN | c.5078G>A p.R1693Q | Missense Mutation (SNP) | VAF 503/1208 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as rs372361501; called by muse, varscan2
- CUL2 | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 486/1101 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772665111, COSV66079115; called by muse, varscan2
- CUL2 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 358/980 reads (37%) | catalogued as rs1554857256, COSV66079665; called by muse, varscan2
- CUZD1 | c.1221G>T p.K407N | Missense Mutation (SNP) | VAF 378/1152 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV100158912; called by muse, varscan2
- CXCL10 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 519/1318 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as rs755610178, COSV60660924; called by muse, varscan2
- CYFIP2 | c.1118C>T p.T373M | Missense Mutation (SNP) | VAF 267/588 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.289); catalogued as rs772567936, COSV100557488; called by muse, varscan2
- CYP2E1 | c.1157G>A p.G386D | Missense Mutation (SNP) | VAF 156/470 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.473); catalogued as COSV99428891; called by muse, varscan2
- CYP7B1 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 558/1416 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775806979, COSV59585812, COSV59593141; ClinVar: uncertain significance; called by muse, varscan2
- CYSLTR2 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 384/936 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs148425155; called by muse, varscan2
- DAPK1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 431/1079 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.092); catalogued as rs548113187, COSV63783988; called by muse, varscan2
- DAPK1 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 564/1328 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1302863111; called by muse, varscan2
- DAPK1 | c.2833C>T p.R945* | Nonsense Mutation (SNP) | VAF 628/1483 reads (42%) | catalogued as COSV63787134; called by muse, varscan2
- DCBLD1 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 391/968 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780427862, COSV51646948; called by muse, varscan2
- DCLK1 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 478/1170 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as COSV99713539; called by muse, varscan2
- DCLK2 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 150/608 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1396258993; called by muse, varscan2
- DCLRE1C | c.1610C>A p.S537Y (on ENST00000378278 / NM_001350965.2; = p.S422Y on NM_022487.4) | Missense Mutation (SNP) | VAF 292/639 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100543249; called by muse, varscan2
- DCLRE1C | c.511C>T p.P171S (on ENST00000378278 / NM_001350965.2; = p.P56S on NM_022487.4) | Missense Mutation (SNP) | VAF 280/774 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as COSV100740034; called by muse, varscan2
- DCP1A | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 524/1291 reads (41%) | catalogued as rs1553688771, COSV53689888; called by muse, varscan2
- DCTD | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 309/1040 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs778735165, COSV63866898; called by muse, varscan2
- DDIAS | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 284/1592 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as rs934243201; called by muse, varscan2
- DDX10 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 702/1718 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as rs369811280; called by muse, varscan2
- DDX11 | c.1529G>C p.G510A | Missense Mutation (SNP) | VAF 176/922 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs561628163; called by muse, varscan2
- DDX23 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 394/891 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs760092244, COSV57285948; called by muse, varscan2
- DDX28 | c.1422C>A p.F474L | Missense Mutation (SNP) | VAF 223/553 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as rs763744932; called by muse, varscan2
- DHRSX | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 339/853 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754962533; called by muse, varscan2
- DHX33 | c.1743G>T p.E581D | Missense Mutation (SNP) | VAF 258/626 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV56580347; called by muse, varscan2
- DICER1 | c.5113G>T p.E1705* | Nonsense Mutation (SNP) | VAF 273/628 reads (43%) | catalogued as COSV58615252, COSV58618257; called by muse, varscan2
- DIS3L2 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 282/581 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1017419118, COSV56053987; called by muse, varscan2
- DLC1 | c.2597G>A p.R866H (on ENST00000276297 / NM_001348081.2; = p.R429H on NM_006094.5) | Missense Mutation (SNP) | VAF 297/752 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV99360394; called by muse, varscan2
- DLGAP1 | c.1942C>T p.R648* | Nonsense Mutation (SNP) | VAF 262/642 reads (41%) | catalogued as COSV59787479; called by muse, varscan2
- DNA2 | c.667G>T p.D223Y | Missense Mutation (SNP) | VAF 396/932 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1251968340, COSV63063067; called by muse, varscan2
- DNAAF5 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 56/409 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as rs773921234; called by muse, varscan2
- DNAH11 | c.6202C>T p.R2068C | Missense Mutation (SNP) | VAF 519/1402 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as rs745332741, COSV60940114; called by muse, varscan2
- DNAH11 | c.6709C>A p.L2237I | Missense Mutation (SNP) | VAF 402/1052 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV104410185; called by muse, varscan2
- DNAH12 | c.2976C>A p.F992L (on ENST00000351747; = p.F1015L on NM_001366028.2) | Missense Mutation (SNP) | VAF 248/1418 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs1379245718, COSV100696755, COSV61064587; called by muse, varscan2
- DNAH3 | c.7653C>A p.F2551L | Missense Mutation (SNP) | VAF 206/432 reads (48%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.559); catalogued as COSV99770569; called by muse, varscan2
- DNAH5 | c.7444C>T p.R2482W | Missense Mutation (SNP) | VAF 386/860 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1355327016; ClinVar: uncertain significance; called by muse, varscan2
- DNAH5 | c.3273G>T p.E1091D | Missense Mutation (SNP) | VAF 346/852 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV54258367; called by muse, varscan2
- DNAH7 | c.9738G>T p.E3246D | Missense Mutation (SNP) | VAF 289/959 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV56771100; called by muse, varscan2
- DNAH7 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 399/1162 reads (34%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.714); catalogued as rs769106832, COSV56764893; called by muse, varscan2
- DNAH8 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 350/984 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.03); catalogued as rs772099828, COSV100545525; called by muse, varscan2
- DNAH9 | c.9274G>A p.A3092T | Missense Mutation (SNP) | VAF 152/969 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.014); catalogued as rs747104009; called by muse, varscan2
- DNAH9 | c.10957G>A p.E3653K | Missense Mutation (SNP) | VAF 326/824 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs780709959, COSV52344199; called by muse, varscan2
- DNAJB14 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 408/1088 reads (38%) | catalogued as COSV62032766; called by muse, varscan2
- DOCK1 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 175/939 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs906422235, COSV54729452; called by muse, varscan2
- DOCK5 | c.161C>A p.S54Y | Missense Mutation (SNP) | VAF 182/974 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs866374107; called by muse, varscan2
- DOCK9 | c.1705C>T p.R569W (on ENST00000376460 / NM_001366676.2; = p.R570W on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 546/698 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750144974; called by muse, varscan2
- DST | c.3272G>A p.R1091Q (on ENST00000361203 / NM_001374722.1; = p.R765Q on NM_001723.6) | Missense Mutation (SNP) | VAF 644/1635 reads (39%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.996); catalogued as rs757291059, COSV55008602; called by muse, varscan2
- DTNB | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 438/1003 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs768951661, COSV56480745; called by muse, varscan2
- DUOX1 | c.4384G>A p.D1462N | Missense Mutation (SNP) | VAF 184/249 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1336261686, COSV99334172; called by muse, varscan2
- DUS3L | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 184/444 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs913443761, COSV100288060; called by muse, varscan2
- DUSP6 | c.830C>A p.S277Y | Missense Mutation (SNP) | VAF 262/628 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV54378306; called by muse, varscan2
- DUXB | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 493/1254 reads (39%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.751); catalogued as rs910913057; called by muse, varscan2
- DYNC2I1 | c.1925G>A p.R642Q | Missense Mutation (SNP) | VAF 297/702 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs1382551742, COSV68105989; called by muse, varscan2
- EDC4 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 344/812 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs751000048; called by muse, varscan2
- EEA1 | c.3391G>T p.E1131* | Nonsense Mutation (SNP) | VAF 323/936 reads (35%) | catalogued as COSV104399648; called by muse, varscan2
- EEF2KMT | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 38/312 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs542077714; called by muse, varscan2
- EFHC2 | c.2078C>A p.S693* | Nonsense Mutation (SNP) | VAF 401/1012 reads (40%) | catalogued as COSV100638095; called by muse, varscan2
- EFL1 | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 422/542 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764747178; called by muse, varscan2
- EFL1 | c.1484T>C p.V495A | Missense Mutation (SNP) | VAF 89/696 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs764789028, COSV51607885; called by muse, varscan2
- EGFLAM | c.989G>T p.R330I | Missense Mutation (SNP) | VAF 634/1468 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV100380536; called by muse, varscan2
- EGR2 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 210/478 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746273681, COSV99653873; called by muse, varscan2
- EGR2 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 200/467 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV54346333; called by muse, varscan2
- EHBP1 | c.2225C>A p.S742Y | Missense Mutation (SNP) | VAF 252/1510 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.165); catalogued as rs1478096570; called by muse, varscan2
- EHBP1L1 | c.1748G>A p.G583E | Missense Mutation (SNP) | VAF 314/734 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV58573614; called by muse, varscan2
- EIF2AK3 | c.1306+1G>A p.X436_splice | Splice Site (SNP) | VAF 402/1018 reads (39%) | catalogued as rs750939022; called by muse, varscan2
- EIF2S3 | c.1119T>G p.I373M | Missense Mutation (SNP) | VAF 313/846 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.694); catalogued as COSV99451109; called by muse, varscan2
- EIF4G3 | c.2104C>T p.R702* | Nonsense Mutation (SNP) | VAF 330/872 reads (38%) | catalogued as COSV99944044; called by muse, varscan2
- ELAPOR2 | c.2221G>T p.E741* (on ENST00000450689 / NM_001142749.3; = p.E574* on NM_152748.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 600/1564 reads (38%) | catalogued as rs557781112, COSV51885969, COSV51891823; called by muse, varscan2
- ELAVL1 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 302/736 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs370407808; called by muse, varscan2
- ELOVL6 | c.93G>T p.K31N | Missense Mutation (SNP) | VAF 384/903 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as COSV56432837; called by muse, varscan2
- EMC2 | c.635G>T p.R212I | Missense Mutation (SNP) | VAF 276/1499 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV55207833, COSV99624454; called by muse, varscan2
- EMILIN3 | c.2197C>T p.R733C | Missense Mutation (SNP) | VAF 216/470 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as rs201529358; called by muse, varscan2
- EML3 | c.2355C>T p.Y785= | Splice Region (SNP) | VAF 282/581 reads (49%) | catalogued as rs1252782458, COSV53873154; called by muse, varscan2
- EMX2 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 330/924 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs1422437499; called by muse, varscan2
- ENGASE | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 168/780 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.876); catalogued as rs547678422, COSV56135272; called by muse, varscan2
- ENGASE | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 267/630 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as rs1371488979, COSV56135041; called by muse, varscan2
- ENTPD3 | c.804G>T p.E268D | Missense Mutation (SNP) | VAF 474/1074 reads (44%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.82); catalogued as COSV100089071; called by muse, varscan2
- EPGN | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 488/1262 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs747900625; called by muse, varscan2
- EPHA7 | c.590C>A p.S197Y | Missense Mutation (SNP) | VAF 589/1520 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65168763; called by muse, varscan2
- ERAP2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 121/1086 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.189); catalogued as rs1186483311, COSV65940771; called by muse, varscan2
- ERBB4 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 592/1350 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as rs569995088, COSV53501451; called by muse, varscan2
- ERVMER34-1 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 516/1250 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.935); catalogued as rs377188202; called by muse, varscan2
- ESCO1 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 374/986 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs373573118; called by muse, varscan2
- EVC | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 338/866 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs1234856967, COSV99381729; called by muse, varscan2
- EYS | c.1901G>T p.R634I | Missense Mutation (SNP) | VAF 556/1344 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1211802318, COSV101005066, COSV65459008, COSV65459327; called by muse, varscan2
- F13A1 | c.1020C>A p.F340L | Missense Mutation (SNP) | VAF 380/962 reads (40%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.537); catalogued as COSV53568563; called by muse, varscan2
- F9 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 476/618 reads (77%) | catalogued as CM010277; called by muse, varscan2
- FAM153A | c.311A>G p.D104G | Missense Mutation (SNP) | VAF 80/744 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.728); catalogued as rs199664058; called by muse, varscan2
- FAM161A | c.1340C>A p.S447Y | Missense Mutation (SNP) | VAF 224/1230 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV56765734; called by muse, varscan2
- FAM185A | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 166/931 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs185867309; called by muse, varscan2
- FAM83B | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 588/1342 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs375679054, COSV60920972; called by muse, varscan2
- FAM83D | c.1344G>T p.E448D | Missense Mutation (SNP) | VAF 261/588 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99465152; called by muse, varscan2
- FAXDC2 | c.406C>A p.L136I | Missense Mutation (SNP) | VAF 298/812 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV100394308; called by muse, varscan2
- FBXW7 | c.833G>A p.R278Q (on ENST00000281708 / NM_001349798.2; = p.R198Q on NM_018315.5) | Missense Mutation (SNP) | VAF 538/1059 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV55928252; called by muse, varscan2
- FER | c.1620G>T p.K540N | Missense Mutation (SNP) | VAF 657/1586 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99812691; called by muse, varscan2
- FGD6 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 374/936 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs1045074245, COSV59691619; called by muse, varscan2
- FLOT1 | c.1229G>A p.R410K | Missense Mutation (SNP) | VAF 362/1000 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1377956339; called by muse, varscan2
- FLT3 | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 82/602 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs1483557529; called by muse, varscan2
- FLYWCH1 | c.1634G>A p.R545H (on ENST00000253928 / NM_001308068.2; = p.R544H on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs771097070, COSV54144040; called by muse, varscan2
- FNDC3A | c.1670T>G p.F557C (on ENST00000492622 / NM_001079673.2; = p.F501C on NM_014923.5) | Missense Mutation (SNP) | VAF 506/1304 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV68132647; called by muse, varscan2
- FRAS1 | c.7085G>A p.R2362Q | Missense Mutation (SNP) | VAF 431/1054 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs865839705, COSV53631054; ClinVar: uncertain significance; called by muse, varscan2
- FREM1 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 462/1141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202362841; called by muse, varscan2
- FRMD3 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 354/840 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs753230861, COSV100171106; called by muse, varscan2
- FRMPD2 | c.3494G>A p.R1165Q | Missense Mutation (SNP) | VAF 334/818 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782228184, COSV59724973; called by muse, varscan2
- FRY | c.3610G>A p.E1204K | Missense Mutation (SNP) | VAF 286/824 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs779292401, COSV66564585; called by muse, varscan2
- FRYL | c.4930C>T p.R1644C | Missense Mutation (SNP) | VAF 407/1104 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as rs150991380; called by muse, varscan2
- FSCB | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 690/1562 reads (44%) | catalogued as rs919384215, COSV100469532; called by muse, varscan2
- FSIP2 | c.20551C>A p.L6851I | Missense Mutation (SNP) | VAF 546/1154 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV58102957; called by muse, varscan2
- FUT10 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 324/843 reads (38%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.972); catalogued as rs758655826; called by muse, varscan2
- FYB2 | c.1929G>T p.K643N | Missense Mutation (SNP) | VAF 482/1242 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs773176269, COSV100599163; called by muse, varscan2
- FZD4 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 432/1072 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776026462, COSV72294363; called by muse, varscan2
- GABRB3 | c.545A>G p.Y182C | Missense Mutation (SNP) | VAF 384/1075 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as CM164376; called by muse, varscan2
- GALNT6 | c.1804G>T p.D602Y | Missense Mutation (SNP) | VAF 290/863 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as COSV62541860; called by muse, varscan2
- GAMT | c.573G>A p.E191= | Splice Region (SNP) | VAF 145/363 reads (40%) | catalogued as COSV99282996; called by muse, varscan2
- GAN | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 402/962 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs886052336, COSV73720719; ClinVar: uncertain significance; called by muse, varscan2
- GAPDHS | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 133/631 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs202022657, COSV55880431; called by muse, varscan2
- GAPVD1 | c.1425G>T p.K475N | Missense Mutation (SNP) | VAF 186/1054 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); catalogued as rs779417104, COSV99782427; called by muse, varscan2
- GAREM1 | c.2331C>A p.F777L (on ENST00000269209 / NM_001242409.2; = p.F776L on NM_022751.3) | Missense Mutation (SNP) | VAF 76/422 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV52507758; called by muse, varscan2
- GASK1A | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 367/972 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs537741985; called by muse, varscan2
- GATAD2A | c.1784C>T p.A595V | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as rs201273478, COSV53078307; called by muse, varscan2
- GCM1 | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 455/1186 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV52523399; called by muse, varscan2
- GDF7 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 144/808 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.049); catalogued as rs1200811138; called by muse, varscan2
- GEMIN4 | c.3039G>T p.E1013D | Missense Mutation (SNP) | VAF 250/561 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as COSV56746520; called by muse, varscan2
- GGA2 | c.491A>G p.D164G | Missense Mutation (SNP) | VAF 178/392 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59167364; called by muse, varscan2
- GGN | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 100/270 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.022); catalogued as rs1308367094; called by muse, varscan2
- GGTLC2 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 158/954 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs891554349, COSV67853952; called by muse, varscan2
- GJA1 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 194/1132 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as rs772121642; ClinVar: uncertain significance; called by muse, varscan2
- GK | c.1318C>A p.L440I (on ENST00000427190 / NM_001205019.2; = p.L434I on NM_000167.6) | Missense Mutation (SNP) | VAF 472/1150 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV66732124; called by muse, varscan2
- GLI2 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 100/486 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.02); catalogued as COSV100082011; called by muse, varscan2
- GLI3 | c.4329C>A p.F1443L | Missense Mutation (SNP) | VAF 323/808 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV67890425; called by muse, varscan2
- GLMN | c.259T>G p.F87V | Missense Mutation (SNP) | VAF 348/888 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as COSV64859957; called by muse, varscan2
- GLP1R | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 392/924 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as rs769668902; called by muse, varscan2
- GLRB | c.1285G>T p.D429Y | Missense Mutation (SNP) | VAF 298/1218 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1302907815, COSV52413689; called by muse, varscan2
- GLUL | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 336/905 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs995971366, COSV59382092; called by muse, varscan2
- GNPTAB | c.2747A>C p.Y916S | Missense Mutation (SNP) | VAF 130/1098 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.929); catalogued as COSV54778723; called by muse, varscan2
- GPR158 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 546/1322 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as rs1235084610, COSV66267181; called by muse, varscan2
- GPR35 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 147/345 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs933185729; called by muse, varscan2
- GPR42 | c.785C>T p.T262M | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1375976102; called by muse, varscan2
- GPRASP2 | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 61/576 reads (11%) | catalogued as COSV59990796, COSV59992583; called by muse, varscan2
- GRIK2 | c.1405G>T p.E469* | Nonsense Mutation (SNP) | VAF 724/1706 reads (42%) | catalogued as COSV59753318; called by muse, varscan2
- GRIPAP1 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 267/732 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs782567085, COSV64553389; called by muse, varscan2
- GRM1 | c.3428C>A p.P1143H | Missense Mutation (SNP) | VAF 181/404 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.72); catalogued as rs745881707, COSV51133540; called by muse, varscan2
- GRM6 | c.2000C>T p.A667V | Missense Mutation (SNP) | VAF 122/299 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs867185590; called by muse, varscan2
- GRTP1 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 216/285 reads (76%) | catalogued as rs781518723, COSV58148386; called by muse, varscan2
- GSS | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 320/756 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs202195412, COSV53813430; called by muse, varscan2
- GTF2H4 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 380/889 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs750545208; called by muse, varscan2
- GTF2I | c.748C>A p.Q250K | Missense Mutation (SNP) | VAF 324/868 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as COSV60399230; called by muse, varscan2
- GTF2IRD2 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 130/768 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs193204072, COSV100736447; called by muse, varscan2
- GUCY2D | c.1870C>T p.R624W | Missense Mutation (SNP) | VAF 244/637 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757230483; ClinVar: uncertain significance; called by muse, varscan2
- HEATR4 | c.2938C>A p.L980I | Missense Mutation (SNP) | VAF 180/964 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs746559676; called by muse, varscan2
- HECTD1 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 539/1280 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV104434315, COSV67946104; called by muse, varscan2
- HECTD3 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 288/669 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs750318785; called by muse, varscan2
- HECTD4 | c.9847G>A p.A3283T | Missense Mutation (SNP) | VAF 186/499 reads (37%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as rs1396290310, COSV66388768; called by muse, varscan2
- HELB | c.1232G>A p.R411K | Missense Mutation (SNP) | VAF 645/1440 reads (45%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99922202; called by muse, varscan2
- HELLS | c.1138C>A p.L380I | Missense Mutation (SNP) | VAF 419/963 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53301437; called by muse, varscan2
- HGD | c.1104G>T p.M368I | Missense Mutation (SNP) | VAF 255/679 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs1315397365; called by muse, varscan2
- HGF | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 368/1896 reads (19%) | catalogued as COSV55950930, COSV55951004; called by muse, varscan2
- HGF | c.131A>T p.K44I | Missense Mutation (SNP) | VAF 430/1104 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV55958672; called by muse, varscan2
- HIPK4 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 132/308 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.778); catalogued as rs772895580, COSV52526505; called by muse, varscan2
- HMCN1 | c.8777G>A p.R2926Q | Missense Mutation (SNP) | VAF 485/1128 reads (43%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.993); catalogued as rs377760099; called by muse, varscan2
- HMCN1 | c.9724C>A p.Q3242K | Missense Mutation (SNP) | VAF 332/798 reads (42%) | SIFT tolerated (0.83); PolyPhen benign (0.038); catalogued as COSV54911046, COSV99635830; called by muse, varscan2
- HMCN1 | c.13535G>A p.R4512Q | Missense Mutation (SNP) | VAF 480/1176 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1473563507, COSV54906034; called by muse, varscan2
- HMCN2 | c.11128G>A p.D3710N | Missense Mutation (SNP) | VAF 242/546 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs780196691; called by muse, varscan2
- HNRNPLL | c.608G>T p.R203I | Missense Mutation (SNP) | VAF 378/1012 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99696573; called by muse, varscan2
- HOMEZ | c.1117T>C p.S373P | Missense Mutation (SNP) | VAF 308/716 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV100664081; called by muse, varscan2
- HPF1 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 233/924 reads (25%) | catalogued as COSV66421701; called by muse, varscan2
- HSPBAP1 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 402/1117 reads (36%) | catalogued as rs1398138748, COSV60241224; called by muse, varscan2
- HSPG2 | c.10121C>T p.A3374V | Missense Mutation (SNP) | VAF 182/474 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1406557824; called by muse, varscan2
- HTR4 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 428/960 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs78403464, COSV100088145; called by muse, varscan2
- HUWE1 | c.4099C>A p.L1367I | Missense Mutation (SNP) | VAF 484/1249 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.095); catalogued as COSV53346324; called by muse, varscan2
- IBSP | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 330/991 reads (33%) | catalogued as rs763570036, COSV56895350; called by muse, varscan2
- IBTK | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 554/1366 reads (41%) | catalogued as rs1373746218, COSV60390806; called by muse, varscan2
- ICA1L | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 81/788 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as COSV100841768, COSV64173631; called by muse, varscan2
- ICAM3 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 160/446 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); catalogued as rs746910528, COSV50329188; called by muse, varscan2
- ICE1 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 374/913 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as rs376008194; called by muse, varscan2
- IDH3A | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 368/514 reads (72%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV51904904, COSV51907282; called by muse, varscan2
- IFNA7 | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 586/1496 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1336499049; called by muse, varscan2
- IFRD1 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 533/1284 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs757387748, COSV50043758; called by muse, varscan2
- IL10RB | c.782C>A p.S261Y | Missense Mutation (SNP) | VAF 107/996 reads (11%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.549); catalogued as COSV51615270; called by muse, varscan2
- IL1R2 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 208/528 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.618); catalogued as rs371567278; called by muse, varscan2
- IL21R | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 44/396 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs374130131; called by muse, varscan2
- IL2RA | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 301/728 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs370516220; called by muse, varscan2
- IL37 | c.575A>C p.K192T | Missense Mutation (SNP) | VAF 169/766 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV54491064; called by muse, varscan2
- IL7R | c.1144C>T p.L382F | Missense Mutation (SNP) | VAF 380/988 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as COSV100286370; called by muse, varscan2
- INKA1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 158/434 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs372678922; called by muse, varscan2
- INSIG2 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 358/1064 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs963738936; called by muse, varscan2
- IQSEC2 | c.1426G>A p.D476N (on ENST00000642864 / NM_001111125.3; = p.D271N on NM_015075.2) | Missense Mutation (SNP) | VAF 284/778 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200182557, COSV100944950; called by muse, varscan2
- IRF6 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 381/932 reads (41%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.892); catalogued as rs1412251145, COSV54213855; called by muse, varscan2
- ISYNA1 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 259/610 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779071108; called by muse, varscan2
- ITCH | c.1297G>T p.E433* (on ENST00000262650 / NM_001257137.3; = p.E392* on NM_031483.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 384/978 reads (39%) | catalogued as COSV52929538; called by muse, varscan2
- ITGA10 | c.481+6C>T | Splice Region (SNP) | VAF 332/750 reads (44%) | catalogued as rs1189543702; called by muse, varscan2
- ITGA6 | c.1736G>A p.R579Q (on ENST00000442250; = p.R540Q on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 132/1240 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as rs1005704533, COSV51221926; called by muse, varscan2
- ITGB3 | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 347/905 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs757590667; called by muse, varscan2
- ITSN1 | c.1032G>T p.K344N | Missense Mutation (SNP) | VAF 434/1098 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.95); catalogued as COSV66082898; called by muse, varscan2
- ITSN1 | c.2797A>C p.N933H | Missense Mutation (SNP) | VAF 242/1268 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1259845651; called by muse, varscan2
- JAG2 | c.418-6C>T | Splice Region (SNP) | VAF 114/324 reads (35%) | catalogued as rs1158542651; called by muse, varscan2
- JARID2 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 266/696 reads (38%) | catalogued as rs371399734; called by muse, varscan2
- JKAMP | c.52G>A p.D18N (on ENST00000554271 / NM_001284201.1; = p.D4N on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 437/1062 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.094); catalogued as rs376416232; called by muse, varscan2
- JRKL | c.324C>A p.F108L | Missense Mutation (SNP) | VAF 571/1322 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0.056); catalogued as COSV53595622; called by muse, varscan2
- KANSL1 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 290/682 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1486084573; called by muse, varscan2
- KASH5 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375328950; called by muse, varscan2
- KAT2B | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 72/584 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55428068; called by muse, varscan2
- KAT2B | c.1489C>A p.H497N | Missense Mutation (SNP) | VAF 470/1042 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55435295; called by muse, varscan2
- KCNA1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 194/1074 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV66838025; called by muse, varscan2
- KCND1 | c.533A>G p.N178S | Missense Mutation (SNP) | VAF 136/360 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as rs1422832720; called by muse, varscan2
- KCNG1 | c.345C>A p.F115L | Missense Mutation (SNP) | VAF 242/530 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV65368581; called by muse, varscan2
- KCNG1 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 269/589 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1481970538; called by muse, varscan2
- KCNMB2 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 374/892 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV64200349; called by muse, varscan2
- KCNT2 | c.3349C>T p.R1117* | Nonsense Mutation (SNP) | VAF 491/1318 reads (37%) | catalogued as rs761594749, COSV54086794, COSV54091830, COSV54099075; called by muse, varscan2
- KCP | c.3048C>A p.C1016* (on ENST00000620378; = p.C1076* on NM_001366122.1) | Nonsense Mutation (SNP) | VAF 152/353 reads (43%) | catalogued as COSV99926379; called by muse, varscan2
- KDM5A | c.3754C>T p.R1252C | Missense Mutation (SNP) | VAF 450/1136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756725945, COSV66991707; called by muse, varscan2
- KDM5B | c.4381C>T p.R1461C | Missense Mutation (SNP) | VAF 154/764 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs765004569, COSV52506637, COSV52510135; called by muse, varscan2
- KDR | c.3352C>T p.R1118* | Nonsense Mutation (SNP) | VAF 339/925 reads (37%) | catalogued as rs373654225; called by muse, varscan2
- KIAA0232 | c.1612C>T p.R538* | Nonsense Mutation (SNP) | VAF 398/1057 reads (38%) | catalogued as rs753266722, COSV56923579; called by muse, varscan2
- KIAA0895L | c.465C>A p.F155L | Missense Mutation (SNP) | VAF 282/702 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51782561; called by muse, varscan2
- KIAA1549L | c.1376C>A p.S459Y (on ENST00000321505; = p.S756Y on NM_012194.3) | Missense Mutation (SNP) | VAF 571/719 reads (79%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as rs1294802740, COSV55773045; called by muse, varscan2
- KIAA1671 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 46/396 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1360461585; called by muse, varscan2
- KIAA2026 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 398/982 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756863980, COSV101199010; called by muse, varscan2
- KIF13B | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 340/838 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as rs1249894225, COSV73054211; called by muse, varscan2
- KIF20A | c.2648C>A p.S883Y | Missense Mutation (SNP) | VAF 371/934 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as rs977795047; called by muse, varscan2
- KLHL25 | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 220/281 reads (78%) | SIFT tolerated (0.13); PolyPhen benign (0.196); catalogued as rs201985058, COSV61995654; called by muse, varscan2
- KLHL4 | c.2081G>T p.R694I | Missense Mutation (SNP) | VAF 472/1198 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs745792102, COSV64140751; called by muse, varscan2
- KLKB1 | c.1652G>T p.R551I | Missense Mutation (SNP) | VAF 191/856 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.347); catalogued as COSV52996194, COSV99249747; called by muse, varscan2
- KMT2A | c.2584C>T p.R862* | Nonsense Mutation (SNP) | VAF 540/1332 reads (41%) | catalogued as COSV63282793; called by muse, varscan2
- KRIT1 | c.139A>C p.K47Q | Missense Mutation (SNP) | VAF 189/1092 reads (17%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.977); catalogued as rs767659177, COSV60667033; called by muse, varscan2
- KRT19 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 233/597 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as rs753522440, COSV54180341; called by muse, varscan2
- KRT74 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 109/584 reads (19%) | catalogued as COSV99977538; called by muse, varscan2
- LAMC3 | c.2049C>A p.F683L | Missense Mutation (SNP) | VAF 299/714 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63088747; called by muse, varscan2
- LARP4 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 100/966 reads (10%) | catalogued as COSV53320826; called by muse, varscan2
- LATS1 | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 260/690 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53591111; called by muse, varscan2
- LCA5 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 636/1592 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs568193819, COSV63971388; called by muse, varscan2
- LDHD | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 252/632 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1352780844; called by muse, varscan2
- LENG8 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 152/386 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs775076605, COSV58727487; called by muse, varscan2
- LGALS16 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 103/944 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.206); catalogued as rs778289181, COSV67425333; called by muse, varscan2
- LIFR | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 574/1378 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.916); catalogued as COSV54701035; called by muse, varscan2
- LONP2 | c.2026C>T p.R676* | Nonsense Mutation (SNP) | VAF 355/873 reads (41%) | catalogued as rs749111858, COSV53521133; called by muse, varscan2
- LPAR6 | c.969G>T p.E323D | Missense Mutation (SNP) | VAF 496/1342 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV57306738, COSV57312653; called by muse, varscan2
- LPIN3 | c.1365G>T p.E455D | Missense Mutation (SNP) | VAF 301/685 reads (44%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.6); catalogued as rs1264530444; called by muse, varscan2
- LRGUK | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 178/1164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751565610, COSV53633960; called by muse, varscan2
- LRP2 | c.6866C>A p.S2289Y | Missense Mutation (SNP) | VAF 342/704 reads (49%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.822); catalogued as COSV55547658; called by muse, varscan2
- LRP2 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 121/1116 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as rs756312774, COSV55544023; called by muse, varscan2
- LRRC36 | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 511/1245 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.51); catalogued as rs754545646, COSV52080701; called by muse, varscan2
- LRRC37A3 | c.4812C>A p.I1604= | Splice Region (SNP) | VAF 328/1090 reads (30%) | catalogued as rs765432047, COSV58534435; called by muse, varscan2
- LRRC37B | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 337/775 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.218); catalogued as COSV58953806; called by muse, varscan2
- LRRC43 | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 220/603 reads (36%) | catalogued as rs1191135772, COSV60290146; called by muse, varscan2
- LRRC49 | c.909G>T p.M303I | Missense Mutation (SNP) | VAF 382/548 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV53007830; called by muse, varscan2
- LRRC4C | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 94/540 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1158836969, COSV53417826; called by muse, varscan2
- LRRC74B | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 198/652 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs576907791; called by muse, varscan2
- LRRIQ1 | c.4156G>T p.E1386* | Nonsense Mutation (SNP) | VAF 440/1268 reads (35%) | catalogued as rs376915402, COSV67826310; called by muse, varscan2
- LRRN4 | c.1784C>T p.S595L | Missense Mutation (SNP) | VAF 140/316 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs746286087, COSV66644696; called by muse, varscan2
- LSM14A | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 401/980 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.446); catalogued as rs149275422, COSV101471689; called by muse, varscan2
- LTV1 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 424/1036 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62536380; called by muse, varscan2
- LUC7L2 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 338/851 reads (40%) | catalogued as COSV54927405; called by muse, varscan2
- LY75 | c.2191C>T p.R731C | Missense Mutation (SNP) | VAF 618/1250 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.606); catalogued as rs1255735605, COSV55104210; called by muse, varscan2
- LZTFL1 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 617/1417 reads (44%) | catalogued as COSV56110841; called by muse, varscan2
- MACC1 | c.2506A>C p.N836H | Missense Mutation (SNP) | VAF 194/1884 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs570639249; called by muse, varscan2
- MAGT1 | c.532-1G>A p.X178_splice (on ENST00000618282 / NM_001367916.1; = p.X210_splice on NM_032121.5) | Splice Site (SNP) | VAF 116/678 reads (17%) | catalogued as COSV63781086; called by muse, varscan2
- MAK16 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 300/726 reads (41%) | catalogued as COSV100789442, COSV64078462; called by muse, varscan2
- MAN2A1 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 538/1324 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422580207, COSV54846865; called by muse, varscan2
- MAN2A1 | c.2942G>A p.R981Q | Missense Mutation (SNP) | VAF 399/1008 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs1287906853; called by muse, varscan2
- MAP3K5 | c.4109G>A p.R1370Q | Missense Mutation (SNP) | VAF 271/620 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62888455; called by muse, varscan2
- MAP3K5 | c.3781C>T p.R1261W | Missense Mutation (SNP) | VAF 274/706 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs267600832, COSV100753431, COSV62886724; called by muse, varscan2
- MAPKBP1 | c.620A>G p.D207G | Missense Mutation (SNP) | VAF 240/314 reads (76%) | SIFT tolerated (0.17); PolyPhen benign (0.444); catalogued as COSV52958035; called by muse, varscan2
- MAST4 | c.2749C>T p.R917* (on ENST00000403625 / NM_001164664.2; = p.R728* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 458/1196 reads (38%) | catalogued as rs1438307359, COSV55133523; called by muse, varscan2
- MB21D2 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 269/754 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs371324905; called by muse, varscan2
- MBNL1 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 454/1027 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.22); catalogued as COSV99219374, COSV99219888; called by muse, varscan2
- MBOAT7 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 234/699 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55477761; called by muse, varscan2
- MDH2 | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 122/736 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.794); catalogued as COSV59885330; called by muse, varscan2
- MEAK7 | c.1197G>T p.E399D | Missense Mutation (SNP) | VAF 384/941 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV59143607; called by muse, varscan2
- MED12L | c.2966G>A p.R989H | Missense Mutation (SNP) | VAF 601/1227 reads (49%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs758782381, COSV56398990; called by muse, varscan2
- MED15 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 92/727 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as rs773788272; called by muse, varscan2
- MEGF6 | c.2386G>A p.D796N | Missense Mutation (SNP) | VAF 173/403 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as rs995194056, COSV53890492; called by muse, varscan2
- MET | c.2552C>A p.S851* | Nonsense Mutation (SNP) | VAF 490/1295 reads (38%) | catalogued as COSV59260929; called by muse, varscan2
- MEX3C | c.1810C>T p.R604* | Nonsense Mutation (SNP) | VAF 136/1212 reads (11%) | catalogued as rs759341802, COSV68529526, COSV68530186; called by muse, varscan2
- MICAL1 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 382/916 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs776656493, COSV62196504; called by muse, varscan2
- MICAL1 | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 224/598 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774894411; called by muse, varscan2
- MICU2 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 176/1050 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs140786216; called by muse, varscan2
- MIS18BP1 | c.1103G>T p.R368I | Missense Mutation (SNP) | VAF 466/1112 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1354654685, COSV60372816; called by muse, varscan2
- MKX | c.615G>T p.E205D | Missense Mutation (SNP) | VAF 532/1320 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1478135013, COSV65391665; called by muse, varscan2
- MLANA | c.182G>T p.S61I | Missense Mutation (SNP) | VAF 344/866 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as rs778135796; called by muse, varscan2
- MLF1 | c.279C>T p.F93= | Splice Region (SNP) | VAF 423/934 reads (45%) | catalogued as rs545017508, COSV63033022; called by muse, varscan2
- MME | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 556/1240 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs145687755, COSV64706075; called by muse, varscan2
- MMEL1 | c.1070C>A p.T357N | Missense Mutation (SNP) | VAF 454/1126 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV56526549; called by muse, varscan2
- MMP17 | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 105/290 reads (36%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.015); catalogued as rs1024293017; called by muse, varscan2
- MMP19 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 434/952 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs764541674, COSV59451381; called by muse, varscan2
- MMRN2 | c.668G>T p.R223I | Missense Mutation (SNP) | VAF 159/364 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV64400647; called by muse, varscan2
- MNS1 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 646/844 reads (77%) | SIFT tolerated (0.09); PolyPhen benign (0.423); catalogued as rs752613858, COSV53068388; called by muse, varscan2
- MOK | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 461/1042 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs370137423; called by muse, varscan2
- MORC1 | c.2165C>T p.T722M | Missense Mutation (SNP) | VAF 552/1168 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs749968839; called by muse, varscan2
- MROH8 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 232/435 reads (53%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as rs754529064, COSV99457866; called by muse, varscan2
- MRPL55 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 434/986 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs375373877; called by muse, varscan2
- MRPS5 | c.350G>T p.R117I | Missense Mutation (SNP) | VAF 442/1066 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs754296900, COSV55534204; called by muse, varscan2
- MSANTD2 | c.1402G>T p.E468* (on ENST00000374979 / NM_001308027.2; = p.E416* on NM_024631.4) | Nonsense Mutation (SNP) | VAF 524/1202 reads (44%) | catalogued as COSV53448485, COSV53448829; called by muse, varscan2
- MSH4 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 442/1012 reads (44%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs5745311; called by muse, varscan2
- MSS51 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 344/856 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs141360683; called by muse, varscan2
- MTFMT | c.893-1G>T p.X298_splice | Splice Site (SNP) | VAF 374/474 reads (79%) | catalogued as COSV54976839; called by muse, varscan2
- MTM1 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 84/734 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60336907; called by muse, varscan2
- MTMR7 | c.1180G>T p.E394* | Nonsense Mutation (SNP) | VAF 511/1250 reads (41%) | catalogued as rs1238407176, COSV51664154; called by muse, varscan2
- MTPAP | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 462/1172 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs570052537, COSV53936894; called by muse, varscan2
- MTR | c.2909T>C p.V970A | Missense Mutation (SNP) | VAF 148/746 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV63965113; called by muse, varscan2
- MTREX | c.204C>A p.F68L | Missense Mutation (SNP) | VAF 352/1042 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV57924091; called by muse, varscan2
- MTRF1 | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 345/874 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99520980; called by muse, varscan2
- MTTP | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 574/1512 reads (38%) | catalogued as COSV55507350, COSV55508194; called by muse, varscan2
- MUC16 | c.42225G>T p.K14075N | Missense Mutation (SNP) | VAF 120/304 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.964); catalogued as COSV66696903; called by muse, varscan2
- MUC16 | c.24317T>G p.F8106C | Missense Mutation (SNP) | VAF 96/457 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.633); catalogued as COSV67463726; called by muse, varscan2
- MUC16 | c.10283C>A p.S3428Y | Missense Mutation (SNP) | VAF 84/519 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV101200032, COSV67488591; called by muse, varscan2
- MUC22 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 584/1338 reads (44%) | SIFT tolerated (0.11); catalogued as rs748531346; called by muse, varscan2
- MXRA5 | c.8251G>A p.V2751M | Missense Mutation (SNP) | VAF 152/849 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141474128; called by muse, varscan2
- MYH6 | c.3405G>T p.E1135D | Missense Mutation (SNP) | VAF 286/966 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768443852; called by muse, varscan2
- MYO16 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 314/422 reads (74%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV51809858; called by muse, varscan2
- N4BP2 | c.4273G>T p.E1425* | Nonsense Mutation (SNP) | VAF 308/723 reads (43%) | catalogued as COSV54706176; called by muse, varscan2
- N4BP2 | c.5064G>T p.Q1688H | Missense Mutation (SNP) | VAF 519/1219 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.412); catalogued as COSV54702009; called by muse, varscan2
- NAA35 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 308/888 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV64484899; called by muse, varscan2
- NARS1 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 196/1032 reads (19%) | catalogued as COSV56877599; called by muse, varscan2
- NBEAL1 | c.1415G>T p.R472I | Missense Mutation (SNP) | VAF 336/894 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.33); catalogued as rs1250367313; called by muse, varscan2
- NCAPD2 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 389/954 reads (41%) | catalogued as rs766616615; called by muse, varscan2
- NCAPG | c.1636G>T p.E546* | Nonsense Mutation (SNP) | VAF 306/832 reads (37%) | catalogued as COSV99266144; called by muse, varscan2
- NCBP3 | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 253/596 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs771163842; called by muse, varscan2
- NCBP3 | c.800A>G p.D267G | Missense Mutation (SNP) | VAF 222/584 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1245937578; called by muse, varscan2
- NCOA6 | c.6056G>A p.R2019Q | Missense Mutation (SNP) | VAF 438/1146 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV62864487, COSV62865553; called by muse, varscan2
- NCOA6 | c.4469C>T p.S1490L | Missense Mutation (SNP) | VAF 326/768 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1288559140, COSV62861530; called by muse, varscan2
- NCOR1 | c.6734G>A p.G2245D | Missense Mutation (SNP) | VAF 248/546 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs1470819892; called by muse, varscan2
- NCOR2 | c.7084G>A p.A2362T | Missense Mutation (SNP) | VAF 156/403 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as rs187448656; called by muse, varscan2
- NDST4 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 572/1336 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52130237; called by muse, varscan2
- NDUFB8 | c.131C>A p.T44N | Missense Mutation (SNP) | VAF 312/630 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54512484; called by muse, varscan2
- NEK1 | c.2804C>T p.S935L | Missense Mutation (SNP) | VAF 215/981 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs755190149, COSV71457843; called by muse, varscan2
- NETO1 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 336/796 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.913); catalogued as rs1269426198, COSV55002393; called by muse, varscan2
- NEU4 | c.793C>T p.R265C (on ENST00000391969 / NM_001167602.3; = p.R277C on NM_080741.4) | Missense Mutation (SNP) | VAF 114/300 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs761329221, COSV57989540, COSV57989643; called by muse, varscan2
- NHEJ1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 273/884 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.124); catalogued as rs773823999, COSV59431533, COSV59433236; called by muse, varscan2
- NINL | c.3790C>T p.R1264C | Missense Mutation (SNP) | VAF 291/668 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as rs560433170, COSV54001804; called by muse, varscan2
- NKX3-1 | c.329C>A p.S110* | Nonsense Mutation (SNP) | VAF 94/848 reads (11%) | catalogued as rs763879828, COSV101082803; called by muse, varscan2
- NLRP4 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 251/558 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as rs775533945, COSV100017297, COSV56712882; called by muse, varscan2
- NOL11 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 424/978 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs1197038288; called by muse, varscan2
- NOS1AP | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 484/1276 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV62633349; called by muse, varscan2
- NOSIP | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 168/887 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs775323843; called by muse, varscan2
- NOTCH1 | c.5917G>A p.A1973T | Missense Mutation (SNP) | VAF 86/470 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs749262588, COSV99491421; called by muse, varscan2
- NPAT | c.1576C>A p.L526I | Missense Mutation (SNP) | VAF 636/1386 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as rs201294142, COSV53719639; called by muse, varscan2
- NPM1 | c.819G>T p.K273N | Missense Mutation (SNP) | VAF 342/876 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.167); catalogued as COSV51548799; called by muse, varscan2
- NPVF | c.36G>T p.L12F | Missense Mutation (SNP) | VAF 250/1342 reads (19%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.909); catalogued as COSV99760266; called by muse, varscan2
- NPY5R | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 248/1086 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs768685790, COSV58452026, COSV58453583; called by muse, varscan2
- NRK | c.3050G>T p.R1017I | Missense Mutation (SNP) | VAF 304/840 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV54596394; called by muse, varscan2
- NSMCE1 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 112/464 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs769578125; called by muse, varscan2
- NT5DC3 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 304/788 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1222229376, COSV104430489; called by muse, varscan2
- NUP160 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 456/544 reads (84%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as rs540295812; called by muse, varscan2
- NUP37 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 531/1338 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs371630269, COSV51838914; called by muse, varscan2
- NXPE2 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 560/1341 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs777667470; called by muse, varscan2
- OBSCN | c.21524G>A p.R7175H | Missense Mutation (SNP) | VAF 288/644 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs377049913; called by muse, varscan2
- OFD1 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 340/684 reads (50%) | catalogued as COSV60797678; called by muse, varscan2
- OOEP | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 221/617 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1239919866; called by muse, varscan2
- OR10J1 | c.83T>G p.F28C | Missense Mutation (SNP) | VAF 402/1000 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71128233; called by muse, varscan2
- OR11H12 | c.255G>T p.E85D | Missense Mutation (SNP) | VAF 481/985 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs1438618980, COSV101612530; called by muse, varscan2
- OR1S1 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 538/1428 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58706701; called by muse, varscan2
- OR2L2 | c.503G>T p.C168F | Missense Mutation (SNP) | VAF 568/1276 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1236218005, COSV100823856; called by muse, varscan2
- OR2M7 | c.534C>A p.C178* | Nonsense Mutation (SNP) | VAF 516/1469 reads (35%) | catalogued as COSV100522738; called by muse, varscan2
- OR4K2 | c.534C>A p.F178L | Missense Mutation (SNP) | VAF 386/1760 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV53848574, COSV53849062; called by muse, varscan2
- OR51G1 | c.20G>A p.S7N | Missense Mutation (SNP) | VAF 280/354 reads (79%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1374502939, COSV58968708; called by muse, varscan2
- OR5H14 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 657/1863 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs370923244; called by muse, varscan2
- OR5K4 | c.953T>A p.F318Y | Missense Mutation (SNP) | VAF 82/472 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.069); catalogued as rs763769508; called by muse, varscan2
- OR6A2 | c.974G>T p.R325I | Missense Mutation (SNP) | VAF 524/654 reads (80%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.102); catalogued as COSV60266072; called by muse, varscan2
- OR9G4 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 483/1306 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.115); catalogued as rs747446138, COSV57248340; called by muse, varscan2
- OR9I1 | c.715T>C p.S239P | Missense Mutation (SNP) | VAF 129/1179 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs755715601; called by muse, varscan2
- OTOR | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 496/1087 reads (46%) | catalogued as COSV99856114, COSV99856311; called by muse, varscan2
- OVCH1 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 496/1202 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as rs745602917, COSV55475623; called by muse, varscan2
- P2RX4 | c.1091G>T p.R364I | Missense Mutation (SNP) | VAF 143/409 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs1052283602, COSV100243105; called by muse, varscan2
- P2RY10 | c.570G>A p.M190I | Missense Mutation (SNP) | VAF 530/1238 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756060182; called by muse, varscan2
- PACS1 | c.2087C>T p.S696L | Missense Mutation (SNP) | VAF 158/376 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.207); catalogued as rs764689853; called by muse, varscan2
- PAFAH2 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 240/594 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs143143905; called by muse, varscan2
- PALMD | c.535A>G p.K179E | Missense Mutation (SNP) | VAF 302/710 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54162912; called by muse, varscan2
- PAPPA | c.2103C>A p.F701L | Missense Mutation (SNP) | VAF 384/954 reads (40%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs1256766728, COSV60293360; called by muse, varscan2
- PAPSS1 | c.1280G>T p.G427V | Missense Mutation (SNP) | VAF 534/1275 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54488852; called by muse, varscan2
- PARP8 | c.2454C>A p.F818L | Missense Mutation (SNP) | VAF 745/1806 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); catalogued as rs777223144; called by muse, varscan2
- PARPBP | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 393/1004 reads (39%) | SIFT tolerated (0.93); PolyPhen benign (0.012); catalogued as rs757038290; called by muse, varscan2
- PBLD | c.480G>T p.K160N | Missense Mutation (SNP) | VAF 187/907 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as rs140699438; called by muse, varscan2
- PCDH10 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 326/600 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV52105550; called by muse, varscan2
- PCDHA7 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 239/1580 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65346672; called by muse, varscan2
- PCDHA8 | c.2359G>A p.E787K | Missense Mutation (SNP) | VAF 510/1313 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs371819535, COSV65324183, COSV65326507; called by muse, varscan2
- PCDHA9 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 293/833 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100969348; called by muse, varscan2
- PCDHB8 | c.95G>T p.R32I | Missense Mutation (SNP) | VAF 401/2622 reads (15%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.01); catalogued as COSV50753851; called by muse, varscan2
- PCLO | c.4798A>G p.K1600E | Missense Mutation (SNP) | VAF 146/1370 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.306); catalogued as COSV61648817; called by muse, varscan2
- PCSK2 | c.399C>T p.I133= | Splice Region (SNP) | VAF 576/1187 reads (49%) | catalogued as rs1048909082; called by muse, varscan2
- PCSK5 | c.890G>T p.R297I | Missense Mutation (SNP) | VAF 294/1424 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV65094096, COSV65095062; called by muse, varscan2
- PCYT1A | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 318/787 reads (40%) | catalogued as COSV99492249; called by muse, varscan2
- PCYT1B | c.840G>T p.E280D | Missense Mutation (SNP) | VAF 413/1115 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs752099580, COSV100770819, COSV63267034; called by muse, varscan2
- PDCD1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 202/544 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.27); catalogued as rs773349951, COSV57692092; called by muse, varscan2
- PDCD10 | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 468/1100 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1311667676; called by muse, varscan2
- PDCD4 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 404/868 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.095); catalogued as COSV54523836; called by muse, varscan2
- PDSS1 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 316/760 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66058884; called by muse, varscan2
- PDZD8 | c.3013G>A p.E1005K | Missense Mutation (SNP) | VAF 390/826 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.907); catalogued as COSV53689314; called by muse, varscan2
- PER3 | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 328/838 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as rs550440452, COSV100728333; called by muse, varscan2
- PGBD1 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 522/1253 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.033); catalogued as rs1487254359; called by muse, varscan2
- PGR | c.2629C>A p.L877I | Missense Mutation (SNP) | VAF 234/1250 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV54809939; called by muse, varscan2
- PHEX | c.602C>A p.S201Y | Missense Mutation (SNP) | VAF 412/1009 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV65074941; called by muse, varscan2
- PHF14 | c.1923G>T p.K641N | Missense Mutation (SNP) | VAF 450/1182 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as COSV68854860; called by muse, varscan2
- PHF7 | c.234C>A p.F78L | Missense Mutation (SNP) | VAF 233/1293 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV59978618, COSV59979768; called by muse, varscan2
- PHKA2 | c.3079G>A p.A1027T | Missense Mutation (SNP) | VAF 196/486 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs142314331; called by muse, varscan2
- PHKB | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 378/923 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs201829990; called by muse, varscan2
- PHTF1 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 616/1459 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs894797072, COSV63368773; called by muse, varscan2
- PIDD1 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 57/448 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs920749342, COSV57194196; called by muse, varscan2
- PIEZO2 | c.3754C>T p.R1252* | Nonsense Mutation (SNP) | VAF 372/912 reads (41%) | catalogued as rs762874609; called by muse, varscan2
- PIK3C2A | c.2375C>A p.S792Y | Missense Mutation (SNP) | VAF 524/696 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56402147, COSV99790723; called by muse, varscan2
- PIK3C2G | c.2701G>T p.E901* (on ENST00000676171; = p.E860* on NM_004570.5) | Nonsense Mutation (SNP) | VAF 528/1277 reads (41%) | catalogued as COSV56816951, COSV56831913; called by muse, varscan2
- PIK3C3 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 373/987 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.524); catalogued as COSV56276336; called by muse, varscan2
- PIK3R3 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 413/1029 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773472193, COSV53104373; called by muse, varscan2
- PIK3R3 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 186/1105 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs775105727; called by muse, varscan2
- PJVK | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 596/1310 reads (45%) | catalogued as rs570669186, COSV100359367; called by muse, varscan2
- PKD2L2 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 388/970 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.069); catalogued as rs1481164509, COSV51797056; called by muse, varscan2
- PKDREJ | c.4315C>T p.P1439S | Missense Mutation (SNP) | VAF 414/563 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs778276544; called by muse, varscan2
- PKHD1L1 | c.12032-1G>T p.X4011_splice | Splice Site (SNP) | VAF 82/600 reads (14%) | catalogued as COSV101005550; called by muse, varscan2
- PKLR | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 258/579 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.695); catalogued as CM981583, COSV61360336; called by muse, varscan2
- PLCL2 | c.2422G>A p.A808T (on ENST00000615277 / NM_001144382.2; = p.A682T on NM_015184.5) | Missense Mutation (SNP) | VAF 116/756 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs148180373; called by muse, varscan2
- PLEKHA1 | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 451/970 reads (46%) | catalogued as rs772494815, COSV64570325; called by muse, varscan2
- PLIN5 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 172/401 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs371504399; called by muse, varscan2
- PLXNC1 | c.2776C>T p.R926W | Missense Mutation (SNP) | VAF 77/488 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.249); catalogued as rs775083313, COSV51571839; called by muse, varscan2
- PNMA2 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 333/816 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs541732199; called by muse, varscan2
- PNMA3 | c.1139C>A p.S380Y | Missense Mutation (SNP) | VAF 102/254 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV100937663; called by muse, varscan2
- PNPLA3 | c.1441C>A p.L481M | Missense Mutation (SNP) | VAF 189/256 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.201); catalogued as COSV53379722; called by muse, varscan2
- POLE | c.1366G>C p.A456P | Missense Mutation (SNP) | VAF 244/622 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1565972665, COSV57673334; ClinVar: uncertain significance; called by muse, varscan2
- PPA2 | c.103T>C p.Y35H | Missense Mutation (SNP) | VAF 252/593 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100049787; called by muse, varscan2
- PPIAL4C | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 52/366 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1447205583; called by muse, varscan2
- PPP1R12B | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 455/1216 reads (37%) | catalogued as COSV100408417; called by muse, varscan2
- PPP1R26 | c.3520C>T p.R1174* | Nonsense Mutation (SNP) | VAF 188/472 reads (40%) | catalogued as rs746358002, COSV100778054; called by muse, varscan2
- PPP1R3F | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 222/556 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV50018242; called by muse, varscan2
- PPP2CA | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 227/558 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV99196032; called by muse, varscan2
- PPP2R3B | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 81/646 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.322); catalogued as rs758656245, COSV66812814; called by muse, varscan2
- PPP2R5C | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 228/592 reads (39%) | catalogued as COSV58270035; called by muse, varscan2
- PPP3CB | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 412/1110 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs751108387, COSV61153858; called by muse, varscan2
- PPP4R4 | c.2367G>T p.E789D | Missense Mutation (SNP) | VAF 408/1003 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs866716040; called by muse, varscan2
- PRAMEF1 | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 343/1061 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs762228466, COSV60004959; called by muse, varscan2
- PRCP | c.1177G>T p.D393Y | Missense Mutation (SNP) | VAF 310/1688 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs1182755784; called by muse, varscan2
- PRDX6 | c.106C>A p.L36I | Missense Mutation (SNP) | VAF 162/1473 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.822); catalogued as rs561003015; called by muse, varscan2
- PRG4 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 562/1298 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0.024); catalogued as rs1030787159, COSV63355420; called by muse, varscan2
- PRIM2 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 506/1328 reads (38%) | catalogued as COSV67295445, COSV67301238; called by muse, varscan2
- PRKACB | c.1003G>T p.D335Y | Missense Mutation (SNP) | VAF 484/1232 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV65761841; called by muse, varscan2
- PRKCA | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 531/1342 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as rs1324531129, COSV99435183; called by muse, varscan2
- PRKDC | c.5326G>T p.E1776* | Nonsense Mutation (SNP) | VAF 586/1427 reads (41%) | catalogued as COSV58046059; called by muse, varscan2
- PRMT3 | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 80/622 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100423724; called by muse, varscan2
- PRMT8 | c.686G>A p.R229K | Missense Mutation (SNP) | VAF 330/810 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV54214544; called by muse, varscan2
- PSMA8 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 371/950 reads (39%) | catalogued as rs139896833; called by muse, varscan2
- PTCHD1 | c.438G>T p.K146N | Missense Mutation (SNP) | VAF 387/932 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.028); catalogued as COSV65062265; called by muse, varscan2
- PTGER4 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 460/1048 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56720584, COSV56721836; called by muse, varscan2
- PTGIS | c.1366T>C p.F456L | Missense Mutation (SNP) | VAF 94/909 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.239); catalogued as rs777270308; called by muse, varscan2
- PTPN6 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 271/720 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.501); catalogued as rs782346134; called by muse, varscan2
- PTPRN | c.2287G>A p.D763N | Missense Mutation (SNP) | VAF 281/578 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs748799144; called by muse, varscan2
- PTPRN | c.2186C>T p.A729V | Missense Mutation (SNP) | VAF 336/717 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1241099555; called by muse, varscan2
- PTPRZ1 | c.6153G>T p.K2051N | Missense Mutation (SNP) | VAF 436/1036 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1372758123, COSV101099740, COSV66436056; called by muse, varscan2
- PWP1 | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 172/754 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs781298018; called by muse, varscan2
- QRICH2 | c.4246C>T p.R1416W | Missense Mutation (SNP) | VAF 170/424 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750903928, COSV53155292; called by muse, varscan2
- QSER1 | c.2495C>T p.S832L (on ENST00000399302; = p.S961L on NM_001076786.3) | Missense Mutation (SNP) | VAF 776/997 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs750245972; called by muse, varscan2
- RAB3GAP1 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 472/1088 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as rs776999297; ClinVar: uncertain significance; called by muse, varscan2
- RABAC1 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 256/628 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs782588625, COSV55770766; called by muse, varscan2
- RACGAP1 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 236/564 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs751070066; called by muse, varscan2
- RAD1 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 452/1180 reads (38%) | catalogued as rs770434727, COSV57715117; called by muse, varscan2
- RAD1 | c.211C>A p.Q71K | Missense Mutation (SNP) | VAF 330/806 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV57715486; called by muse, varscan2
- RADX | c.1454T>G p.F485C | Missense Mutation (SNP) | VAF 267/775 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV65318164; called by muse, varscan2
- RAG1 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 283/844 reads (34%) | SIFT tolerated, low confidence (0.8); PolyPhen probably damaging (0.96); catalogued as rs748211230, COSV55024075; called by muse, varscan2
- RALGAPA1 | c.3709C>A p.L1237I | Missense Mutation (SNP) | VAF 254/733 reads (35%) | SIFT tolerated (0.94); PolyPhen benign (0.175); catalogued as rs1407735093; called by muse, varscan2
- RALGAPA1 | c.2543G>A p.R848Q | Missense Mutation (SNP) | VAF 449/1062 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.122); catalogued as COSV99354976; called by muse, varscan2
- RALGPS1 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 364/954 reads (38%) | catalogued as rs781621744, COSV52231820; called by muse, varscan2
- RAPGEF2 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 282/1096 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs771969316, COSV52425304; called by muse, varscan2
- RASD1 | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 386/892 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.098); catalogued as rs760122866; called by muse, varscan2
- RASSF4 | c.790G>A p.V264M | Missense Mutation (SNP) | VAF 298/674 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs554573808, COSV58487474; called by muse, varscan2
- RBL2 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 376/961 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as rs1182315458, COSV50872893, COSV50882509; called by muse, varscan2
- RBM12B | c.2088G>T p.E696D | Missense Mutation (SNP) | VAF 408/856 reads (48%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.006); catalogued as COSV67898936; called by muse, varscan2
- RBM34 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 336/890 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV64012446; called by muse, varscan2
- RBM46 | c.1243T>C p.Y415H | Missense Mutation (SNP) | VAF 382/1240 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.039); catalogued as rs756278661; called by muse, varscan2
- RBM47 | c.702G>T p.E234D | Missense Mutation (SNP) | VAF 78/752 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.73); catalogued as COSV55931796, COSV55945560; called by muse, varscan2
- RBM48 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 488/1204 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs777152272, COSV56003127; called by muse, varscan2
- RC3H1 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 588/1420 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775347375, COSV104383481; called by muse, varscan2
- RECQL5 | c.2808G>A p.E936= | Splice Region (SNP) | VAF 226/580 reads (39%) | catalogued as rs1442269581; called by muse, varscan2
- REL | c.535+1G>A p.X179_splice | Splice Site (SNP) | VAF 346/913 reads (38%) | catalogued as COSV54362359, COSV54366495; called by muse, varscan2
- RELCH | c.3311C>A p.S1104Y | Missense Mutation (SNP) | VAF 474/1150 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs764407663; called by muse, varscan2
- RELN | c.2738G>A p.R913H | Missense Mutation (SNP) | VAF 488/1269 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs764757536; called by muse, varscan2
- REPS1 | c.1425C>T p.S475= | Splice Region (SNP) | VAF 547/1356 reads (40%) | catalogued as rs141996588; called by muse, varscan2
- REPS2 | c.1659G>T p.K553N | Missense Mutation (SNP) | VAF 240/617 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV58181271; called by muse, varscan2
- RET | c.1035C>A p.S345R | Missense Mutation (SNP) | VAF 138/742 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.287); catalogued as COSV60690267; called by muse, varscan2
- RFC1 | c.2471G>A p.R824Q (on ENST00000381897 / NM_001363496.2; = p.R823Q on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 239/1150 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1178128210, COSV62901605; called by muse, varscan2
- RFC1 | c.557G>T p.R186I | Missense Mutation (SNP) | VAF 408/982 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV100568047; called by muse, varscan2
- RFPL1 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 560/726 reads (77%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV62978674; called by muse, varscan2
- RFTN2 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 110/1083 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as rs748520765; called by muse, varscan2
- RFWD3 | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 346/802 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs1466710989, COSV63097724; called by muse, varscan2
- RFX3 | c.1066C>A p.L356I | Missense Mutation (SNP) | VAF 502/1312 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.15); catalogued as COSV100175730; called by muse, varscan2
- RGPD8 | c.4573T>C p.S1525P | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs1364957954; called by muse, varscan2
- RGS16 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 481/1149 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs1480790468, COSV100842507; called by muse, varscan2
- RHPN2 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 266/604 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as rs766256907; called by muse, varscan2
- RIC1 | c.3405A>C p.K1135N | Missense Mutation (SNP) | VAF 546/1300 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.158); catalogued as rs766996809; called by muse, varscan2
- RNASE12 | c.252G>T p.K84N | Missense Mutation (SNP) | VAF 178/460 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV60087618; called by muse, varscan2
- RNF111 | c.1061C>A p.S354Y | Missense Mutation (SNP) | VAF 197/678 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs764700130, COSV100788906; called by muse, varscan2
- RNF17 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 364/897 reads (41%) | catalogued as COSV55037382; called by muse, varscan2
- RNF17 | c.1752G>T p.Q584H | Missense Mutation (SNP) | VAF 115/990 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99691993; called by muse, varscan2
- RNF6 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 386/990 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1321583362, COSV104413826; called by muse, varscan2
- ROBO2 | c.2770C>T p.L924F | Missense Mutation (SNP) | VAF 668/1668 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs982912843; called by muse, varscan2
- ROS1 | c.3445G>A p.E1149K | Missense Mutation (SNP) | VAF 756/1794 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as rs775665843, COSV63850723; called by muse, varscan2
- RPL7L1 | c.178C>T p.R60* | Nonsense Mutation (SNP) | VAF 312/974 reads (32%) | catalogued as rs1235048977, COSV59035119; called by muse, varscan2
- RPS6KA2 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 386/736 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs748313908; called by muse, varscan2
- RSPH10B | c.2327C>T p.A776V | Missense Mutation (SNP) | VAF 376/1278 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs145755299; called by muse, varscan2
- RYR3 | c.4210C>T p.R1404W | Missense Mutation (SNP) | VAF 436/552 reads (79%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.959); catalogued as rs367755953, COSV66801559; ClinVar: uncertain significance; called by muse, varscan2
- SAE1 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 251/668 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.324); catalogued as rs1245017238, COSV54293925; called by muse, varscan2
- SAFB2 | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 174/434 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs754078815, COSV53044412, COSV99386165; called by muse, varscan2
- SALL4 | c.1871C>T p.T624M | Missense Mutation (SNP) | VAF 94/510 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs146604877, COSV53852490; ClinVar: uncertain significance / benign; called by muse, varscan2
- SAMD9 | c.2151G>T p.M717I | Missense Mutation (SNP) | VAF 466/1013 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV66077723; called by muse, varscan2
- SAP18 | c.223G>T p.E75* (on ENST00000607003; = p.E94* on NM_005870.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 196/930 reads (21%) | catalogued as COSV66822820; called by muse, varscan2
- SAXO1 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 256/577 reads (44%) | SIFT tolerated (0.89); PolyPhen benign (0.036); catalogued as rs41312810; called by muse, varscan2
- SCARB2 | c.994+5G>T | Splice Region (SNP) | VAF 86/846 reads (10%) | catalogued as rs950616504; called by muse, varscan2
- SCN11A | c.5002C>A p.L1668I | Missense Mutation (SNP) | VAF 496/1031 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.1); catalogued as rs752566267, COSV56570457; called by muse, varscan2
- SCN7A | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 387/896 reads (43%) | catalogued as rs1343706993; called by muse, varscan2
- SCRN3 | c.1138G>T p.E380* | Nonsense Mutation (SNP) | VAF 398/1156 reads (34%) | catalogued as rs888428309; called by muse, varscan2
- SDSL | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 160/435 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as rs770711798; called by muse, varscan2
- SEPTIN10 | c.1260C>A p.F420L | Missense Mutation (SNP) | VAF 223/1174 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.224); catalogued as COSV61779835; called by muse, varscan2
- SEPTIN3 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 184/242 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs767061908, COSV52172179; called by muse, varscan2
- SERINC2 | c.274C>T p.L92F (on ENST00000373709 / NM_178865.5; = p.L96F on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 194/450 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs782133304; called by muse, varscan2
- SERPINB13 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 136/829 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs191405968, COSV54028622; called by muse, varscan2
- SETD2 | c.7378G>A p.A2460T | Missense Mutation (SNP) | VAF 542/1442 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as COSV57440500; called by muse, varscan2
- SETD2 | c.5236G>T p.E1746* | Nonsense Mutation (SNP) | VAF 548/1360 reads (40%) | catalogued as COSV57430307; called by muse, varscan2
- SFRP2 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 346/690 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV56836828; called by muse, varscan2
- SH3BGRL | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 386/1051 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64623012; called by muse, varscan2
- SHCBP1 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 529/1312 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs376160881; called by muse, varscan2
- SHCBP1L | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 491/1210 reads (41%) | catalogued as COSV62353556; called by muse, varscan2
- SHH | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 219/531 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51919190; called by muse, varscan2
- SHKBP1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 110/316 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773904593, COSV52541662; called by muse, varscan2
- SHMT2 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 106/834 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985002692; called by muse, varscan2
- SHROOM1 | c.1672G>T p.D558Y | Missense Mutation (SNP) | VAF 170/844 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774835802; called by muse, varscan2
- SHROOM3 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 326/816 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755595009; called by muse, varscan2
- SIK2 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 587/1312 reads (45%) | catalogued as rs1292123220, COSV59250108; called by muse, varscan2
- SIK3 | c.1843G>A p.A615T (on ENST00000445177 / NM_001366686.2; = p.A573T on NM_001281749.3) | Missense Mutation (SNP) | VAF 172/1059 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.145); catalogued as COSV52617404; called by muse, varscan2
- SKAP1 | c.442+2T>C p.X148_splice | Splice Site (SNP) | VAF 141/377 reads (37%) | catalogued as COSV100412249; called by muse, varscan2
- SLC10A4 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 174/439 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs765943369; called by muse, varscan2
- SLC15A2 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 382/1056 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs267599571, COSV55196140; called by muse, varscan2
- SLC15A3 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 186/414 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.354); catalogued as rs769755986; called by muse, varscan2
- SLC15A5 | c.1033C>T p.L345F | Missense Mutation (SNP) | VAF 573/1371 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as rs1451578534; called by muse, varscan2
- SLC24A3 | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 426/958 reads (44%) | catalogued as rs1052212745; called by muse, varscan2
- SLC25A53 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 106/709 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs12862951, COSV62460285, COSV62460933; called by muse, varscan2
- SLC2A13 | c.1172G>T p.R391I | Missense Mutation (SNP) | VAF 399/1081 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55114080; called by muse, varscan2
- SLC4A4 | c.1313G>A p.R438Q (on ENST00000264485 / NM_001098484.3; = p.R394Q on NM_003759.4) | Missense Mutation (SNP) | VAF 356/832 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as rs1169489768, COSV52615734; called by muse, varscan2
- SLC4A5 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 301/678 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs374813637, COSV61024573; called by muse, varscan2
- SLC5A8 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 276/684 reads (40%) | SIFT tolerated (0.81); PolyPhen benign (0.045); catalogued as COSV73310428, COSV73311196; called by muse, varscan2
- SLC6A13 | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 432/977 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV58257276; called by muse, varscan2
- SLFN5 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 360/891 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200108679, COSV55479923; called by muse, varscan2
- SLIT3 | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 264/662 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs751014310; called by muse, varscan2
- SMC4 | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 89/702 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100643902; called by muse, varscan2
- SMCHD1 | c.5659C>T p.R1887W | Missense Mutation (SNP) | VAF 546/1264 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1462790313, COSV99861486; called by muse, varscan2
- SMTNL2 | c.732G>T p.E244D (on ENST00000389313 / NM_001114974.2; = p.E100D on NM_198501.3) | Missense Mutation (SNP) | VAF 66/376 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.168); catalogued as COSV58809433; called by muse, varscan2
- SNED1 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 137/329 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs1374681775; called by muse, varscan2
- SNRNP25 | c.358C>T p.R120* (on ENST00000383018; = p.R111* on NM_024571.4) | Nonsense Mutation (SNP) | VAF 178/681 reads (26%) | catalogued as rs150984532; called by muse, varscan2
- SORBS1 | c.2182G>T p.E728* (on ENST00000361941 / NM_001034954.2; = p.E434* on NM_006434.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 132/1072 reads (12%) | catalogued as rs767500426; called by muse, varscan2
- SORCS2 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 274/686 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1401426205, COSV61164781; called by muse, varscan2
- SOX6 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 252/1380 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.2); catalogued as rs545452739, COSV57048270; called by muse, varscan2
- SPCS1 | c.479G>T p.R160I (on ENST00000233025; = p.R93I on NM_014041.5) | Missense Mutation (SNP) | VAF 438/1010 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV99236959; called by muse, varscan2
2,400 further variants in this file (1,230 protein-altering or splice-affecting, 454 silent, 716 other) are not listed here.
